Somatic mutation profile of tumor specimen 0DNWKS from CCDI case PBCBMZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.2 years (4,467 days).
Specimen 0DNWKS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e2b3b32-7f7b-43c9-88e3-752ce4249e27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8cba383-560c-4c6b-9db9-d572a6af5d73

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 2, 5'UTR 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP251 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs751028061, COSV56611348; called by muse, mutect2, varscan2
- HGS | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs745478862; called by muse, mutect2
- NAV3 | c.6254C>A p.A2085E (on ENST00000397909 / NM_001024383.2; = p.A2063E on NM_014903.6) | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.848); catalogued as COSV99886899; called by muse, mutect2, varscan2
- OTC | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs148660170; called by muse, mutect2, varscan2
- SORL1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 132/374 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751192763, CM164106, COSV99494271; called by muse, mutect2, varscan2
- TBR1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417745; called by muse, mutect2
- AMPH | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- CDC25C | c.725A>G p.K242R | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- DCTN4 | c.560G>T p.R187M | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.855); called by muse, mutect2
- KMT2C | c.13690C>T p.Q4564* | Nonsense Mutation (SNP) | VAF 171/389 reads (44%) | called by muse, mutect2, varscan2
- TRIM33 | c.761A>C p.H254P | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- ZCCHC8 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFHR4 | c.675G>A p.P225= (on ENST00000367416 / NM_001201551.2; = p.P226= on NM_001201550.3) | Silent (SNP) | VAF 31/396 reads (8%) | catalogued as rs779045232, COSV52223848; called by muse, mutect2
- MAST3 | c.1422G>A p.T474= | Silent (SNP) | VAF 34/321 reads (11%) | catalogued as rs770437108; called by muse, mutect2, varscan2
- PKHD1L1 | c.7722T>C p.N2574= | Silent (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- PRDM1 | c.1734C>T p.N578= | Silent (SNP) | VAF 191/459 reads (42%) | catalogued as COSV100959017; called by muse, mutect2, varscan2
- DUT | c.281-68G>A | Intron (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- ITLN1 | c.-2C>G | 5'UTR (SNP) | VAF 83/206 reads (40%) | called by muse, mutect2, varscan2
- KANK1 | c.*83C>G | 3'UTR (SNP) | VAF 43/105 reads (41%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5361C>A | Intron (SNP) | VAF 111/394 reads (28%) | catalogued as COSV99962862; called by muse, mutect2, varscan2
